Somatic mutation profile of tumor specimen TCGA-FS-A1ZM-06A (aliquot TCGA-FS-A1ZM-06A-12D-A197-08) from TCGA case TCGA-FS-A1ZM, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 79.0 years (28,849 days).
Specimen TCGA-FS-A1ZM-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70fa1a4c-6667-4ebe-8705-60f7c93a3128.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZM-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZM-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49334dbf-aab7-4b50-a940-16d9e7646fbb

The open-access MAF lists 282 somatic variants for this specimen: 194 protein-altering or splice-affecting, 84 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 178, Silent 84, Nonsense Mutation 9, Frame Shift Del 3, Splice Region 3, Intron 2, 5'Flank 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, varscan2
- CLEC14A | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs1470716755, COSV60561634; called by mutect2, varscan2
- KRT5 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs58619430, CM062805, COSV52863886; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1888G>A p.E630K (on ENST00000404938 / NM_001163941.2; = p.E185K on NM_178559.6) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV51722530; called by mutect2, varscan2
- ABLIM1 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV53317549; called by muse, mutect2, varscan2
- ACO1 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs537741206, COSV59385166; called by mutect2, varscan2
- ACSF2 | c.757T>C p.S253P | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs1270026427; called by muse, mutect2, varscan2
- ADAMTS20 | c.2972C>T p.S991F | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV67137437, COSV67140882; called by muse, varscan2
- ADGRG6 | c.1660T>C p.F554L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.08); catalogued as COSV51602318; called by muse, mutect2, varscan2
- AGBL1 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV69792845; called by muse, mutect2, varscan2
- AGO1 | c.2275C>T p.R759* | Nonsense Mutation (SNP) | VAF 19/38 reads (50%) | catalogued as COSV64596680; called by muse, mutect2, varscan2
- AHDC1 | c.4090C>G p.H1364D | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV55942869; called by muse, mutect2, varscan2
- ALDH7A1 | c.1037T>C p.V346A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1405914019, COSV63161127; called by muse, mutect2, varscan2
- ALPK1 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 88/250 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV51592863; called by muse, mutect2, varscan2
- AMER1 | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs754938624, COSV57658266; called by muse, mutect2, varscan2
- ANKRD12 | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1278671700, COSV50854461; called by mutect2, varscan2
- AP002512.3 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1278477054, COSV54409326; called by muse, mutect2, varscan2
- ARG1 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV51582049; called by mutect2, varscan2
- ASB10 | c.1316G>A p.G439D (on ENST00000420175 / NM_001142459.2; = p.G424D on NM_080871.4) | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV52000919; called by muse, mutect2, varscan2
- ASH1L | c.4412C>T p.P1471L | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV64214684; called by muse, mutect2, varscan2
- ASXL1 | c.4031C>T p.S1344F | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.162); catalogued as COSV60122289; called by muse, mutect2, varscan2
- BLZF1 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV61395071; called by muse, mutect2, varscan2
- BRINP3 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs367902400, COSV66524676; called by muse, mutect2, varscan2
- BTNL3 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.971); catalogued as COSV61566014; called by muse, mutect2, varscan2
- BTNL8 | c.674-1G>A p.X225_splice | Splice Site (SNP) | VAF 28/221 reads (13%) | catalogued as COSV51461651, COSV51462428; called by muse, mutect2, varscan2
- CCDC141 | c.3578A>G p.D1193G | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55384082; called by muse, mutect2, varscan2
- CCDC158 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV66357175; called by muse, mutect2, varscan2
- CD5L | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV63823349; called by muse, mutect2, varscan2
- CDH17 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV50327136; called by muse, mutect2, varscan2
- CELSR2 | c.5209C>G p.L1737V | Missense Mutation (SNP) | VAF 205/447 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.199); catalogued as COSV54780395; called by muse, mutect2, varscan2
- CGN | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.272); catalogued as COSV54974313; called by muse, mutect2, varscan2
- CHD1 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52345316; called by mutect2, varscan2
- CHD1 | c.1746A>T p.K582N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV99399277; called by muse, mutect2, varscan2
- CHST8 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52856992; called by mutect2, varscan2
- CMTR1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 379/463 reads (82%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as COSV65091866; called by muse, mutect2, varscan2
- CNKSR1 | c.998C>T p.P333L (on ENST00000374253 / NM_001297647.2; = p.P326L on NM_006314.3) | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV64164387; called by muse, varscan2
- CXCR2 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV59282323; called by muse, mutect2, varscan2
- DAB1 | c.884C>T p.P295L (on ENST00000371231; = p.P262L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV64693070; called by muse, varscan2
- DDX24 | c.688A>G p.K230E | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as rs1391444415, COSV58213953; called by muse, mutect2, varscan2
- DDX53 | c.301A>T p.M101L | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.266); catalogued as COSV60070160; called by muse, mutect2, varscan2
- DENND2B | c.275G>T p.C92F | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.047); catalogued as COSV100567326; called by muse, varscan2
- DIP2A | c.2903C>G p.S968C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV100595540; called by muse, mutect2, varscan2
- DNAH11 | c.8039C>T p.P2680L | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV60985785; called by muse, mutect2
- DNAH11 | c.12753T>A p.V4251= | Splice Region (SNP) | VAF 25/142 reads (18%) | catalogued as COSV60985810; called by muse, mutect2, varscan2
- DNER | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59162499; called by muse, mutect2, varscan2
- DSC3 | c.2313G>A p.M771I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs867992638, COSV64572539; called by mutect2, varscan2
- DYSF | c.3413A>G p.N1138S | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV50637966; called by muse, mutect2
- EIF4A3 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53922311; called by muse, mutect2, varscan2
- ELP1 | c.3475C>T p.H1159Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV65900309; called by muse, mutect2, varscan2
- EPN1 | c.958C>T p.P320S (on ENST00000270460 / NM_001321263.1; = p.P295S on NM_013333.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs1202662066, COSV50035953; called by muse, mutect2, varscan2
- ERG | c.667C>A p.P223T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV55740344, COSV99065902; called by muse, mutect2, varscan2
- EYA1 | c.884T>G p.L295W | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV58175655; called by muse, mutect2, varscan2
- EYA4 | c.1537A>G p.K513E (on ENST00000531901 / NM_001301013.1; = p.K507E on NM_004100.5) | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV62062045; called by muse, mutect2, varscan2
- FANCD2 | c.4403C>T p.P1468L | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV55047742; called by muse, mutect2, varscan2
- FBXL5 | c.1592G>T p.S531I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV58014316; called by muse, mutect2, varscan2
- FILIP1 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs776455963, COSV52725973; called by muse, mutect2, varscan2
- FKBPL | c.578C>G p.T193S | Missense Mutation (SNP) | VAF 84/607 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); catalogued as COSV64322928; called by muse, mutect2, varscan2
- FMNL1 | c.312G>A p.W104* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV58959912; called by muse, mutect2, varscan2
- FSHB | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV54221887; called by mutect2, varscan2
- FXYD6 | c.190A>G p.S64G | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.487); catalogued as COSV52805452; called by muse, varscan2
- FYB2 | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755054806, COSV58589792, COSV58589976; called by muse, mutect2, varscan2
- GPC2 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1186680604; called by mutect2, varscan2
- GPR158 | c.3128C>T p.S1043F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1374104989, COSV66264976, COSV66273219; called by muse, mutect2, varscan2
- GPRC6A | c.2648C>A p.P883H | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59956374; called by mutect2, varscan2
- HECW1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67822349; called by muse, mutect2, varscan2
- IDE | c.1115T>A p.F372Y | Missense Mutation (SNP) | VAF 54/270 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV56425205; called by mutect2, varscan2
- IGSF22 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV60039351; called by muse, mutect2, varscan2
- IL15RA | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs765326957, COSV66093309; called by muse, mutect2, varscan2
- IL1R1 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs188550005, COSV52108737; called by muse, mutect2, varscan2
- IQCH | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs769295973, COSV60061030; called by muse, mutect2, varscan2
- KDM5A | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 110/160 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV66996768; called by muse, mutect2, varscan2
- KMT2D | c.15223G>A p.G5075R | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764161037, COSV56479053, COSV99040273, COSV99985342; called by muse, mutect2, varscan2
- KRT20 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV99071865; called by muse, mutect2, varscan2
- KRT84 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs374447110; called by muse, mutect2, varscan2
- KRT9 | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 5/33 reads (15%) | PolyPhen possibly damaging (0.604); catalogued as COSV55855747; called by muse, mutect2, varscan2
- KYNU | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748827582, COSV51582784; called by mutect2, varscan2
- LATS2 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.992); catalogued as COSV101231513; called by muse, mutect2
- LGALS12 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55372107; called by muse, mutect2, varscan2
- LOXL2 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV66693114, COSV66693929; called by muse, varscan2
- LSM10 | c.345G>A p.W115* | Nonsense Mutation (SNP) | VAF 13/93 reads (14%) | catalogued as COSV59872738; called by muse, mutect2, varscan2
- MAP7 | c.2186G>A p.G729E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as COSV63423452; called by muse, mutect2, varscan2
- MAPK12 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.045); catalogued as COSV53136192; called by muse, mutect2, varscan2
- MB | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as COSV63094619; called by muse, mutect2, varscan2
- MDH2 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782289550, COSV59885425; called by muse, mutect2, varscan2
- MED12L | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.48); catalogued as rs868783221, COSV56368501, COSV56385433; called by muse, mutect2, varscan2
- MED17 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as rs746738191, COSV52600145; called by muse, varscan2
- MGAM | c.5398G>A p.E1800K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs267601328, COSV72073671; called by mutect2, varscan2
- MICALL1 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV53243782; called by muse, mutect2, varscan2
- MIER3 | c.1053G>A p.T351= (on ENST00000381199 / NM_001297599.2; = p.T350= on NM_152622.4) | Splice Region (SNP) | VAF 20/222 reads (9%) | catalogued as rs369881757; called by muse, mutect2
- MTM1 | c.155T>C p.I52T | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV60338001; called by muse, mutect2, varscan2
- MUC16 | c.6758C>T p.S2253F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV67440914, COSV67481611; called by muse, varscan2
- MYH1 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 64/259 reads (25%) | catalogued as COSV56851295; called by muse, mutect2, varscan2
- MYT1L | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV67734413; called by muse, mutect2, varscan2
- N4BP2 | c.3275T>C p.L1092P | Missense Mutation (SNP) | VAF 72/117 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54707790; called by muse, mutect2, varscan2
- NAALAD2 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58966933; called by muse, mutect2, varscan2
- NCAM2 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.095); catalogued as COSV53107459; called by muse, mutect2
- NHSL2 | c.994G>A p.E332K (on ENST00000510661; = p.E698K on NM_001013627.2) | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as rs1387057806, COSV65455268; called by muse, mutect2, varscan2
- NID1 | c.3232C>T p.L1078F | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99936919, COSV99937270; called by muse, mutect2, varscan2
- NKX2-2 | c.340A>G p.N114D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV65820476; called by muse, varscan2
- NOL4 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99305789; called by muse, mutect2, varscan2
- NOL4 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52353619; called by muse, mutect2, varscan2
- NOSIP | c.362T>G p.I121S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as COSV100182183; called by muse, mutect2, varscan2
- NRG3 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.901); catalogued as rs749884304, COSV64544784; called by muse, mutect2, varscan2
- NRXN1 | c.4081G>A p.D1361N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60526410; called by mutect2, varscan2
- NT5E | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV57628838; called by muse, mutect2, varscan2
- NUTM1 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.913); catalogued as rs1225708114, COSV61548676; called by muse, mutect2, varscan2
- OR10A3 | c.341T>G p.L114R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100660245; called by muse, mutect2, varscan2
- OR10J3 | c.743T>A p.V248E | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV100171667; called by muse, mutect2, varscan2
- OR10J3 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100171670; called by muse, mutect2, varscan2
- OR4A47 | c.707C>A p.S236* | Nonsense Mutation (SNP) | VAF 14/118 reads (12%) | catalogued as COSV71445186; called by mutect2, varscan2
- OR52E2 | c.268A>G p.N90D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV100384737; called by muse, mutect2, varscan2
- OR5K4 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV61583481, COSV61583769; called by muse, mutect2, varscan2
- OR9Q1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1565098750, COSV59048469; called by muse, mutect2, varscan2
- PARM1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV56660667; called by muse, mutect2, varscan2
- PARP9 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64451497; called by muse, mutect2, varscan2
- PCDHB4 | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.049); catalogued as COSV52027700; called by muse, mutect2, varscan2
- PDS5B | c.3348G>C p.M1116I | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV59733587, COSV59735554; called by muse, varscan2
- PI4KB | c.1265G>A p.R422Q (on ENST00000368873 / NM_001369623.1; = p.R434Q on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1267222624, COSV55022226; called by mutect2, varscan2
- PKD1L1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 107/228 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV56980060; called by muse, varscan2
- PLEKHG4B | c.997G>C p.G333R (on ENST00000283426; = p.G689R on NM_052909.5) | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV52056407; called by muse, mutect2, varscan2
- PLS3 | c.255A>C p.K85N | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV56782729; called by muse, mutect2, varscan2
- POM121L12 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs777785485, COSV101374905, COSV68693279, COSV68694022; called by muse, mutect2, varscan2
- PPP1R10 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1038956169, COSV64740649; called by muse, mutect2, varscan2
- PPRC1 | c.4108C>G p.L1370V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV53389134; called by muse, mutect2, varscan2
- PRAMEF12 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV63216849, COSV63216878; called by muse, mutect2, varscan2
- PRSS12 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs367867526; called by muse, mutect2, varscan2
- PTBP3 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as COSV57587999; called by muse, mutect2
- RBM11 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as COSV101271194; called by muse, mutect2, varscan2
- RGMB | c.191T>A p.V64E (on ENST00000513185 / NM_001366508.1; = p.V105E on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/223 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57567288; called by muse, mutect2, varscan2
- RGS21 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 67/115 reads (58%) | SIFT tolerated (0.48); PolyPhen benign (0.063); catalogued as rs370635184; called by muse, mutect2, varscan2
- RNASE10 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV60517701, COSV60517742; called by muse, mutect2, varscan2
- RNF38 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV52397725; called by muse, mutect2, varscan2
- RNF40 | c.2662C>T p.Q888* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100221991; called by mutect2, varscan2
- ROS1 | c.5962G>A p.D1988N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100876784; called by muse, mutect2, varscan2
- RP1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55128589; called by muse, mutect2, varscan2
- RP1L1 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs267601690; called by muse, varscan2
- RPS11 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV54527382; called by muse, mutect2, varscan2
- RSKR | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV56384294; called by muse, mutect2, varscan2
- SBK2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.216); catalogued as rs1170960401, COSV60014492; called by muse, mutect2, varscan2
- SEMA5B | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs1025612235, COSV52109827; called by muse, mutect2, varscan2
- SERPINB3 | c.1094G>A p.C365Y | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769288329, COSV52194793; called by muse, mutect2, varscan2
- SERPINB7 | c.251T>G p.F84C | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as COSV60536162; called by muse, mutect2, varscan2
- SHANK3 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV53192091; called by muse, mutect2, varscan2
- SHCBP1L | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV62356727; called by muse, mutect2, varscan2
- SLC16A14 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); catalogued as rs1404835517, COSV54617472, COSV99725656; called by mutect2, varscan2
- SLC22A16 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57935461; called by muse, varscan2
- SLC6A20 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV62073079; called by muse, varscan2
- SMCHD1 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs920749551, COSV55253061, COSV55261839; called by muse, mutect2, varscan2
- SNX12 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV52146746; called by muse, mutect2, varscan2
- SNX31 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV61265312; called by muse, varscan2
- SORCS2 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61184835; called by muse, mutect2, varscan2
- SPNS3 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1170234642, COSV61072563; called by muse, mutect2, varscan2
- SSTR5 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs553515967, COSV53513670; called by muse, mutect2
- STMN2 | c.198A>T p.E66D | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99626304; called by mutect2, varscan2
- STMN2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.272); catalogued as COSV99626305; called by mutect2, varscan2
- SUPV3L1 | c.1213C>T p.L405F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1422223987, COSV62846523; called by muse, mutect2, varscan2
- SVEP1 | c.3461C>T p.S1154F | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs1352947184, COSV57049769; called by muse, mutect2, varscan2
- SYT7 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV55660059; called by muse, mutect2, varscan2
- TANC1 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV55098715; called by muse, mutect2, varscan2
- TARBP1 | c.2500C>T p.H834Y | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV50211222; called by muse, varscan2
- TBC1D9 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV71309385; called by muse, mutect2, varscan2
- TBCK | c.1235C>T p.P412L (on ENST00000273980 / NM_001163436.4; = p.P349L on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as COSV56763768; called by muse, mutect2, varscan2
- TBX15 | c.1762G>A p.G588R (on ENST00000369429 / NM_001330677.2; = p.G482R on NM_152380.3) | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52877202; called by muse, mutect2, varscan2
- TCF3 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.541); catalogued as COSV53654182; called by muse, mutect2, varscan2
- TLE4 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs866711978, COSV54629940; called by muse, mutect2, varscan2
- TLR7 | c.2168G>A p.R723K | Missense Mutation (SNP) | VAF 55/79 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66125744; called by muse, mutect2, varscan2
- TM9SF2 | c.1378G>C p.G460R | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.16); catalogued as rs1396008775, COSV64507677; called by muse, varscan2
- TMEM184A | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as COSV52476242; called by muse, mutect2, varscan2
- TNRC18 | c.8413C>T p.R2805C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV100078645; called by mutect2, varscan2
- TOGARAM1 | c.1870T>A p.C624S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV61889515; called by muse, mutect2, varscan2
- TOGARAM1 | c.4043C>T p.A1348V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV63895657; called by muse, mutect2, varscan2
- TP53BP1 | c.273C>T p.D91= | Splice Region (SNP) | VAF 53/128 reads (41%) | catalogued as COSV55511083; called by muse, mutect2, varscan2
- TTN | c.39095G>T p.R13032L (on ENST00000591111; = p.R5608L on NM_003319.4) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | PolyPhen probably damaging (0.998); catalogued as COSV60121330; called by muse, mutect2, varscan2
- TTN | c.24863C>A p.A8288D (on ENST00000591111; = p.A7361D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | PolyPhen probably damaging (1); catalogued as COSV100602696; called by muse, varscan2
- TTN | c.11378G>A p.G3793E (on ENST00000591111; = p.G3747E on NM_003319.4) | Missense Mutation (SNP) | VAF 60/143 reads (42%) | catalogued as COSV60089656, COSV60432217; called by muse, mutect2, varscan2
- TXNDC2 | c.1603G>A p.D535N (on ENST00000306084 / NM_001098529.2; = p.D468N on NM_032243.6) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as rs753851182, COSV60156290; called by muse, mutect2, varscan2
- UGT2B10 | c.149A>C p.H50P | Missense Mutation (SNP) | VAF 94/223 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55324348; called by muse, mutect2, varscan2
- UNC13D | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV52888047; called by muse, mutect2, varscan2
- VWC2 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV61487545; called by muse, mutect2
- WASHC4 | c.2780G>A p.R927Q | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1305038419, COSV59892753; called by muse, varscan2
- WDR53 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV60284010, COSV60285136; called by muse, varscan2
- WDR72 | c.2021G>A p.W674* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV64747349; called by muse, mutect2, varscan2
- XKR5 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs761406823, COSV68398969; called by muse, mutect2
- ZNF106 | c.787T>C p.W263R | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs139622071; called by muse, mutect2, varscan2
- ZNF142 | c.4708G>A p.D1570N (on ENST00000411696 / NM_001379660.1; = p.D1370N on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs537789697, COSV68746164; called by muse, mutect2, varscan2
- ZNF277 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV62466513; called by muse, mutect2, varscan2
- ZNF282 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50485147; called by muse, mutect2, varscan2
- ZNF479 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.069); catalogued as rs1300207130, COSV58638477; called by muse, mutect2, varscan2
- ZNF611 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as COSV60539989; called by muse, mutect2, varscan2
- ZSWIM3 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV54852136; called by muse, mutect2, varscan2
- KMT2E | c.601del p.E201Nfs*15 | Frame Shift Del (DEL) | VAF 38/199 reads (19%) | called by mutect2, pindel, varscan2
- QRICH1 | c.25_32del p.I9* | Frame Shift Del (DEL) | VAF 17/113 reads (15%) | called by mutect2, pindel, varscan2
- TRAV13-1 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- TYK2 | c.36_48del p.S12Rfs*13 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- ABCC3 | c.3762C>T p.I1254= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as rs756282585, COSV53330623; called by muse, mutect2, varscan2
- ADNP | c.1395C>T p.F465= | Silent (SNP) | VAF 81/289 reads (28%) | catalogued as rs375629425; called by muse, mutect2, varscan2
- AHR | c.727T>C p.L243= | Silent (SNP) | VAF 56/103 reads (54%) | catalogued as COSV54126946; called by muse, mutect2, varscan2
- ANK3 | c.13092G>A p.T4364= (on ENST00000280772 / NM_001320874.2; = p.T988= on NM_001149.3) | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as rs775425679, COSV55046749; called by mutect2, varscan2
- ANKRD30A | c.480C>T p.S160= (on ENST00000611781; = p.S104= on NM_052997.2) | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV64603742; called by muse, mutect2, varscan2
- ARMC5 | c.336C>T p.S112= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1173357427, COSV51660379; called by muse, mutect2, varscan2
- ASTN1 | c.3150C>T p.I1050= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs150457018; called by muse, mutect2, varscan2
- C1orf87 | c.612C>T p.I204= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as COSV64599230; called by muse, mutect2, varscan2
- C7orf26 | c.720C>T p.L240= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as rs776924817, COSV60420790; called by mutect2, varscan2
- CABP2 | c.609C>T p.L203= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV53709985; called by muse, mutect2, varscan2
- CBLIF | c.210G>A p.K70= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV57240657; called by muse, mutect2, varscan2
- CCBE1 | c.1011C>T p.F337= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV67951795; called by muse, mutect2, varscan2
- CDH17 | c.816C>T p.S272= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as rs1412967476, COSV99217186; called by muse, mutect2, varscan2
- CFTR | c.2454G>A p.L818= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as rs1182328637, COSV50117452; called by muse, mutect2, varscan2
- CNTN6 | c.2196G>A p.E732= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV63192247; called by muse, mutect2, varscan2
- CSMD3 | c.5265G>A p.L1755= (on ENST00000297405 / NM_001363185.1; = p.L1651= on NM_052900.3) | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV52340762; called by mutect2, varscan2
- DIP2A | c.2904C>T p.S968= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs751372562; called by mutect2, varscan2
- DSCAM | c.3708G>A p.E1236= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV68037876; called by muse, mutect2, varscan2
- ENOX1 | c.1518C>T p.S506= | Silent (SNP) | VAF 60/198 reads (30%) | catalogued as COSV54921387; called by muse, mutect2, varscan2
- FAT3 | c.5232C>T p.T1744= | Silent (SNP) | VAF 118/564 reads (21%) | catalogued as rs1292924502, COSV53183002; called by muse, mutect2, varscan2
- GAL3ST3 | c.693G>A p.V231= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV61749795; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.387C>T p.I129= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs887325531, COSV61322335; called by mutect2, varscan2
- GPC2 | c.936C>T p.S312= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV99444476; called by muse, mutect2, varscan2
- H1-5 | c.525G>A p.K175= | Silent (SNP) | VAF 57/119 reads (48%) | catalogued as COSV58901717; called by muse, mutect2, varscan2
- HADHB | c.480C>T p.I160= | Silent (SNP) | VAF 42/159 reads (26%) | catalogued as rs775200563, COSV58544779; called by muse, mutect2, varscan2
- HIC2 | c.1410C>T p.F470= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV68043029; called by mutect2, varscan2
- HIVEP1 | c.2019T>G p.S673= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV65105541; called by muse, mutect2, varscan2
- HSPB3 | c.162T>A p.P54= | Silent (SNP) | VAF 81/108 reads (75%) | catalogued as COSV57357501; called by muse, mutect2, varscan2
- IGKV1D-17 | c.51C>T p.F17= | Silent (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- IGSF21 | c.621G>A p.Q207= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs868350157, COSV52145999; called by muse, mutect2, varscan2
- IL7R | c.894C>T p.F298= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV57405582; called by muse, mutect2, varscan2
- IRAG2 | c.3411C>T p.S1137= (on ENST00000636465; = p.S182= on NM_006152.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 150/199 reads (75%) | catalogued as rs555465090, COSV100611706, COSV63141193; called by muse, mutect2, varscan2
- KCNJ6 | c.207C>T p.N69= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as rs201815398; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNQ3 | c.1500G>A p.R500= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV66483649; called by muse, mutect2, varscan2
- KCTD8 | c.1053C>T p.S351= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as COSV63598298; called by muse, mutect2, varscan2
- KRT20 | c.132C>T p.I44= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV99391351; called by muse, mutect2, varscan2
- LSR | c.1257A>C p.R419= (on ENST00000361790; = p.R400= on NM_015925.6) | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV55888505; called by muse, mutect2, varscan2
- MAP2K7 | c.33C>T p.S11= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV60719422; called by muse, mutect2, varscan2
- MC3R | c.762C>T p.C254= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV54765196; called by muse, mutect2, varscan2
- MSANTD4 | c.705C>T p.I235= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as rs539432553, COSV57287094; called by mutect2, varscan2
- MYH3 | c.4407G>A p.E1469= | Silent (SNP) | VAF 35/158 reads (22%) | catalogued as COSV56870821; called by muse, mutect2, varscan2
- NCOR2 | c.3132G>A p.G1044= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs978787899, COSV62305799; called by muse, mutect2
- NDUFAF5 | c.672C>T p.D224= | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as rs1199767012, COSV65247946; called by muse, mutect2, varscan2
- NID1 | c.3231C>T p.N1077= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as rs757630278, COSV99937273; called by muse, mutect2, varscan2
- NOMO1 | c.2064C>T p.I688= | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as rs543693028, COSV55061798; called by muse, mutect2, varscan2
- NOSIP | c.363C>T p.I121= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs371941851; called by mutect2, varscan2
- OR10A3 | c.342C>T p.L114= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV62459806; called by muse, mutect2, varscan2
- OR14A16 | c.276C>T p.F92= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV62927247, COSV62927615; called by muse, mutect2, varscan2
- OR7C1 | c.681G>A p.R227= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV50184723; called by muse, mutect2, varscan2
- OR8B8 | c.78C>T p.P26= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100045163, COSV60145985; called by muse, mutect2, varscan2
- PDE6B | c.126G>A p.P42= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs533513647, COSV55325063; called by muse, mutect2, varscan2
- PKD2L2 | c.234T>C p.F78= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as COSV51802283; called by muse, mutect2, varscan2
- PLCH1 | c.3573G>A p.E1191= (on ENST00000340059 / NM_001130960.2; = p.E1183= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs1180033291, COSV58189211; called by muse, mutect2, varscan2
- POMGNT1 | c.1407G>A p.P469= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs375039269; called by muse, mutect2, varscan2
- PRB2 | c.696C>T p.S232= | Silent (SNP) | VAF 87/567 reads (15%) | catalogued as COSV66984447; called by muse, varscan2
- PSMF1 | c.477C>T p.P159= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs1256915558, COSV55676474; called by muse, mutect2, varscan2
- PTCD2 | c.315G>A p.R105= | Silent (SNP) | VAF 49/112 reads (44%) | catalogued as COSV57339439; called by muse, mutect2, varscan2
- PTPRU | c.930C>T p.S310= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV60537706; called by muse, mutect2, varscan2
- RACK1 | c.600C>T p.V200= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as COSV59322768; called by muse, varscan2
- RAD50 | c.1986C>T p.A662= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs777890524, COSV54758348; ClinVar: likely benign; called by muse, mutect2, varscan2
- RBM11 | c.453A>T p.P151= | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as COSV101271193; called by muse, mutect2, varscan2
- RNF40 | c.2661C>T p.I887= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100221989; called by muse, mutect2, varscan2
- RP1 | c.3894C>T p.F1298= | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as COSV55115168; called by muse, mutect2, varscan2
- RTP5 | c.621C>T p.S207= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1559458007, COSV58321678; called by muse, mutect2, varscan2
- SERPINB11 | c.438G>A p.R146= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV66956493; called by muse, mutect2, varscan2
- SH3BP4 | c.102C>T p.S34= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV60646937; called by muse, mutect2, varscan2
- SLC39A12 | c.1200C>T p.I400= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs1478185966, COSV66196468, COSV66202987; called by muse, mutect2, varscan2
- SNX33 | c.426C>T p.P142= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV57914815; called by muse, varscan2
- SPZ1 | c.129C>T p.S43= | Silent (SNP) | VAF 21/157 reads (13%) | catalogued as COSV57064822; called by muse, mutect2, varscan2
- SRGAP3 | c.1848C>T p.I616= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV64538386; called by muse, mutect2, varscan2
- ST3GAL6 | c.84C>T p.V28= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV99504669; called by muse, mutect2, varscan2
- SYT1 | c.339G>A p.T113= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs758911259, COSV54078439, COSV99693511; called by mutect2, varscan2
- TLE4 | c.435C>T p.P145= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as rs3186577, COSV54625751; called by muse, mutect2, varscan2
- TMPRSS4 | c.9G>A p.Q3= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1185558292, COSV71110707; called by muse, mutect2, varscan2
- TNRC18 | c.8412C>T p.A2804= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1398354735, COSV100078678; called by muse, mutect2, varscan2
- TRIM10 | c.285G>A p.E95= | Silent (SNP) | VAF 23/190 reads (12%) | catalogued as COSV64990608; called by muse, mutect2, varscan2
- TRIM58 | c.1347C>T p.F449= | Silent (SNP) | VAF 55/114 reads (48%) | catalogued as COSV63569018; called by muse, mutect2, varscan2
- TXNDC2 | c.174C>T p.A58= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV60154985; called by muse, mutect2, varscan2
- VHLL | c.195C>T p.I65= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs761621541, COSV60554183; called by mutect2, varscan2
- VPS13D | c.6070C>T p.L2024= | Silent (SNP) | VAF 48/101 reads (48%) | catalogued as rs1211576612, COSV50699894; called by muse, mutect2, varscan2
- WNT3A | c.552C>T p.N184= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV52732853, COSV52734531; called by muse, mutect2, varscan2
- ZNF155 | c.633G>A p.K211= | Silent (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- ZNF436 | c.1104G>A p.G368= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as COSV58358384; called by muse, mutect2, varscan2
- ZNF80 | c.789G>A p.Q263= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV57360164, COSV57362857; called by muse, mutect2, varscan2
- CYP11B1 | c.396-576C>T | Intron (SNP) | VAF 11/52 reads (21%) | catalogued as COSV52830807; called by muse, mutect2, varscan2
- DEFB119 | c.61+1225T>C | Intron (SNP) | VAF 53/192 reads (28%) | catalogued as rs769942062, COSV59268361; called by muse, mutect2, varscan2
- ELAVL4 | chr1:50106355 G>A | 5'Flank (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100836649; called by muse, mutect2, varscan2
- SNORD115-31 | n.24T>C | RNA (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
